Somatic mutation profile of tumor specimen C3N-02523-01 (aliquot CPT0234930007) from CPTAC case C3N-02523, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 61.4 years (22,428 days).
Specimen C3N-02523-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b84b57b0-5bdb-4792-aaa6-f53a0d63f78e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02523-71 (Blood Derived Normal), aliquot CPT0235050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/239e9743-d4c8-4e92-9087-950cc0632e79

The open-access MAF lists 358 somatic variants for this specimen: 231 protein-altering or splice-affecting, 85 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 85, Intron 14, Nonsense Mutation 13, RNA 12, 5'UTR 6, Frame Shift Del 5, 3'UTR 5, Splice Region 4, Frame Shift Ins 4, 5'Flank 3, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.7202G>T p.R2401L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794728756, CM056049, CM065451, COSV63663412; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 173/296 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55969378; called by muse, mutect2, varscan2
- ADGRG4 | c.5350G>T p.V1784F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs755692382; called by muse, mutect2, varscan2
- AKR1B15 | c.159del p.G54Afs*3 | Frame Shift Del (DEL) | VAF 103/552 reads (19%) | catalogued as COSV71151272; called by mutect2, pindel, varscan2
- ANKRD30A | c.3902T>G p.M1301R (on ENST00000611781; = p.M1245R on NM_052997.2) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs766238481; called by muse, mutect2, varscan2
- ARHGAP44 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs767616267, COSV52388695; called by muse, mutect2, varscan2
- ATAT1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs377239422; called by muse, mutect2, varscan2
- BRINP3 | c.83G>T p.W28L | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.055); catalogued as rs970443809; called by muse, mutect2, varscan2
- C10orf71 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV100109731; called by muse, mutect2, varscan2
- CD300LB | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58726791; called by muse, mutect2, varscan2
- CHIA | c.1069G>A p.A357T (on ENST00000343320; = p.A249T on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201691527; called by muse, mutect2, varscan2
- CHRNB2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 159/634 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs79646221, COSV100872623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN2 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 105/1154 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.735); catalogued as rs867302883; called by muse, mutect2
- COL11A1 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62174754; called by muse, mutect2, varscan2
- CSF2RB | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 493/928 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99454213; called by muse, mutect2, varscan2
- CSMD3 | c.10315C>T p.Q3439* (on ENST00000297405 / NM_001363185.1; = p.Q3270* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 32/273 reads (12%) | catalogued as COSV52319623; called by muse, mutect2, varscan2
- DCC | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59119739; called by muse, mutect2, varscan2
- DNER | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100518794; called by muse, mutect2, varscan2
- EFEMP1 | c.-7-3G>C | Splice Region (SNP) | VAF 116/426 reads (27%) | catalogued as rs1219489996, COSV62617144; called by muse, mutect2, varscan2
- EYS | c.7871C>T p.T2624I | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs1474376614; called by muse, mutect2, varscan2
- FAM135B | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.926); catalogued as COSV50531448, COSV50534873; called by muse, mutect2, varscan2
- FAT1 | c.9229+1G>T p.X3077_splice | Splice Site (SNP) | VAF 29/80 reads (36%) | catalogued as COSV101499479, COSV71673360; called by muse, mutect2, varscan2
- FBXO4 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55851576; called by muse, mutect2, varscan2
- FGFR1OP2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs746155998; called by muse, mutect2, varscan2
- FLRT2 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58139396; called by muse, mutect2, varscan2
- FLT1 | c.2810A>G p.H937R | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs1429337906; called by muse, mutect2
- FMC1-LUC7L2 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1334722512; called by muse, mutect2, varscan2
- GOLGA8S | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 166/1014 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs751781887; called by muse, mutect2, varscan2
- GPR158 | c.2394C>A p.N798K | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV100893304; called by muse, mutect2, varscan2
- H2AC15 | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1373696728; called by muse, mutect2, varscan2
- HECW1 | c.2098_2112del p.A700_S704del | In Frame Del (DEL) | VAF 49/325 reads (15%) | catalogued as rs754299049; called by mutect2, varscan2
- HEPH | c.521C>T p.T174I (on ENST00000343002; = p.T228I on NM_138737.5) | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100295041; called by muse, mutect2, varscan2
- IL7R | c.1107C>A p.C369* | Nonsense Mutation (SNP) | VAF 519/761 reads (68%) | catalogued as rs199803084, COSV100286751; called by muse, mutect2, varscan2
- KMT2D | c.4162_4169dup p.E1391Gfs*29 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | catalogued as CI1313023; called by mutect2, varscan2
- KMT2E | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs909158740; called by muse, mutect2, varscan2
- LGR5 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 219/392 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.403); catalogued as COSV57003877, COSV57010910; called by muse, mutect2, varscan2
- LRRC31 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as rs1468818379; called by muse, varscan2
- LTBP2 | c.4719G>T p.T1573= | Splice Region (SNP) | VAF 250/576 reads (43%) | catalogued as rs763812721, COSV100000826; called by muse, mutect2, varscan2
- MKNK1 | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs764607258; called by muse, mutect2, varscan2
- MMRN1 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs755427850; called by muse, mutect2, varscan2
- MUC3A | c.7847C>A p.P2616Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs1030660720; called by muse, mutect2, varscan2
- MYH4 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV55114460; called by muse, mutect2, varscan2
- MYO7B | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936305918, COSV101268412; called by muse, mutect2, varscan2
- NANOGNB | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV66124825; called by muse, mutect2, varscan2
- NSD1 | c.4546G>T p.E1516* | Nonsense Mutation (SNP) | VAF 29/406 reads (7%) | catalogued as COSV100729144; called by muse, mutect2
- OR10A2 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 174/332 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1253457990, COSV100224992; called by muse, mutect2, varscan2
- OR4N2 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755540433; called by muse, mutect2, varscan2
- OR4P4 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV104406400; called by muse, mutect2, varscan2
- PAPPA2 | c.4267T>G p.C1423G | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201672637; called by mutect2, varscan2
- PCDHAC1 | c.2717C>A p.S906Y | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53838187; called by muse, mutect2, varscan2
- PCLO | c.13558G>T p.G4520C | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433910; called by muse, mutect2, varscan2
- PDK1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56374481; called by muse, mutect2, varscan2
- PKHD1L1 | c.5653C>G p.P1885A | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65748599; called by muse, mutect2, varscan2
- PKHD1L1 | c.7496A>G p.Y2499C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs751294174; called by muse, mutect2, varscan2
- PNMA8A | c.726G>C p.R242S | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs764258634, COSV100562394; called by muse, mutect2
- POM121L12 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 87/415 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV68692287; called by muse, mutect2, varscan2
- PRB2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV66982083; called by muse, varscan2
- PURG | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs754379218, COSV59570773; called by muse, mutect2, varscan2
- RADIL | c.330C>A p.Y110* | Nonsense Mutation (SNP) | VAF 114/264 reads (43%) | catalogued as rs575762308, COSV68201259, COSV68201630; called by muse, mutect2, varscan2
- RPS6KC1 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs182116576, COSV65303017; called by muse, mutect2, varscan2
- SEMA3E | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV57111339; called by muse, mutect2, varscan2
- SEPTIN1 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs1414774097; called by muse, mutect2, varscan2
- SHANK1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 126/502 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs539761857; called by muse, mutect2, varscan2
- SLC45A2 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 30/910 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1361457938, COSV99672431; called by muse, mutect2
- SLITRK3 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 59/469 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53854611; called by muse, mutect2, varscan2
- SNRPN | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.079); catalogued as COSV100578739; called by muse, mutect2, varscan2
- SULT6B1 | c.608A>G p.Y203C (on ENST00000535679 / NM_001367551.1; = p.Y165C on NM_001032377.2) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53195688; called by muse, mutect2, varscan2
- TGM2 | c.435G>T p.A145= | Splice Region (SNP) | VAF 96/412 reads (23%) | catalogued as COSV63931501; called by muse, mutect2, varscan2
- THNSL2 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs751496181; called by muse, mutect2, varscan2
- TRIM58 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV63571487; called by muse, mutect2, varscan2
- USP35 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1342436825; called by muse, mutect2, varscan2
- ZBTB4 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334590967, COSV60984121; called by muse, varscan2
- ZFP36 | c.716C>T p.S239F (on ENST00000594442; = p.S233F on NM_003407.5) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs1281441466; called by muse, mutect2, varscan2
- ZFR2 | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV53596338; called by muse, mutect2, varscan2
- ZFYVE28 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs764438656, COSV52108508; called by muse, mutect2
- ZNF217 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs768762589; called by muse, mutect2, varscan2
- ZNF225 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53473059; called by muse, mutect2, varscan2
- ZNF236 | c.4922C>G p.S1641C | Missense Mutation (SNP) | VAF 90/478 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99471511; called by muse, mutect2, varscan2
- ZNF703 | c.1498del p.A500Pfs*43 | Frame Shift Del (DEL) | VAF 146/1198 reads (12%) | catalogued as rs1285771801; called by pindel, varscan2
- ABCA12 | c.7231C>A p.L2411I (on ENST00000272895 / NM_173076.3; = p.L2093I on NM_015657.3) | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ABCC5 | c.2992A>T p.I998F | Missense Mutation (SNP) | VAF 74/678 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4312G>A p.A1438T | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- ADGRA1 | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 31/627 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- AKAP8L | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- AKAP8L | c.1218C>G p.S406R | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- AQP1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 116/475 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ARHGAP20 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ASCC2 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 74/433 reads (17%) | called by muse, mutect2, varscan2
- ATF2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ATP10D | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ATP8A1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATXN7 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AXL | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- BCR | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3169G>T p.V1057L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C1QL2 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBWD5 | c.1071G>C p.L357F (on ENST00000382405 / NM_001330668.1; = p.L309F on NM_001024916.3) | Missense Mutation (SNP) | VAF 43/425 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.26); called by mutect2, varscan2
- CDH12 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 54/574 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- CDH7 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CEP76 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAMP1 | c.893C>G p.P298R | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CNTNAP2 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.3254T>A p.L1085* | Nonsense Mutation (SNP) | VAF 136/420 reads (32%) | called by muse, mutect2, varscan2
- COL4A5 | c.4803+3A>C | Splice Region (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- CR1 | c.452C>A p.T151N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CRISP2 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSF1R | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD2 | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CSMD3 | c.8172C>A p.S2724R | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CUX1 | c.224A>T p.E75V (on ENST00000292535 / NM_181552.4; = p.E86V on NM_001913.5) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CXCL6 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 152/684 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCHS2 | n.5424-2A>T | Splice Site (SNP) | VAF 31/91 reads (34%) | called by muse, varscan2
- DNAH8 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- DOCK1 | c.834G>C p.L278F | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPYSL2 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 111/258 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.985); called by muse, varscan2
- EMC2 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- ERCC6 | c.3720T>G p.S1240R | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ETV4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- FAM184B | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXL13 | c.991C>A p.L331I | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FIGNL2 | c.1023A>T p.Q341H | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOCAD | c.921A>T p.E307D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXE3 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT13 | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GALNT14 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GARRE1 | c.2129C>G p.P710R | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GFRA4 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 76/380 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GOLGA8T | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GPC6 | c.1465dup p.S489Kfs*2 | Frame Shift Ins (INS) | VAF 59/273 reads (22%) | called by mutect2, pindel, varscan2
- H1-10 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H4C9 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- HCN1 | c.785T>A p.I262N | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- HEPACAM2 | c.338A>G p.Q113R (on ENST00000394468 / NM_001039372.4; = p.Q101R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEPHL1 | c.1714C>G p.Q572E | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- HOXC9 | c.667T>A p.Y223N | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- HTR4 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICAM5 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 128/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- IGHV1-58 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGKV3D-11 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 183/718 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- IL2 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ITIH5 | c.1890G>T p.M630I | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, varscan2
- ITPR2 | c.4968G>T p.L1656F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KIF4B | c.3127G>T p.D1043Y | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- KLK14 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLK2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLRC3 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- KRTAP4-11 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 91/484 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by mutect2, varscan2
- LCOR | c.3625G>A p.D1209N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX8 | c.281G>C p.C94S | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRAT | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.243del p.G82Dfs*6 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- LRRIQ4 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.194); called by muse, mutect2
- LRRK2 | c.6791T>A p.L2264* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MEF2A | c.1159G>C p.G387R (on ENST00000557942 / NM_001319206.2; = p.G381R on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINDY3 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC16 | c.41895G>C p.Q13965H | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MUC17 | c.6092G>T p.G2031V | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MUC3A | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MYO3A | c.3599T>C p.V1200A | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAA35 | c.841C>G p.H281D | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NHSL1 | c.739A>T p.T247S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NKAPL | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NKX2-2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 430/913 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRC3 | c.2387del p.K796Rfs*7 | Frame Shift Del (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- NME1-NME2 | c.523dup p.L175Pfs*11 (on ENST00000555572; = p.L150Pfs*11 on NM_001018136.3) | Frame Shift Ins (INS) | VAF 126/594 reads (21%) | called by mutect2, pindel, varscan2
- NOVA1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NRBP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/124 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2
- OLR1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2AK2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR2M4 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2W3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR52N5 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR56B1 | c.341A>T p.H114L | Missense Mutation (SNP) | VAF 136/279 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- OR56B4 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR8H3 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PACRGL | c.406A>T p.K136* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- PATJ | c.2719del p.H907Tfs*39 | Frame Shift Del (DEL) | VAF 34/149 reads (23%) | called by mutect2, pindel, varscan2
- PCDHGA9 | c.1361A>T p.Q454L | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PEG3 | c.1234A>T p.R412W | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PHKB | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLXNA4 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 119/529 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POMGNT1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 131/485 reads (27%) | PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PPP1R32 | c.1043+1G>T p.X348_splice | Splice Site (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- PREX2 | c.1784dup p.L595Ffs*3 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- PRG2 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- PRKD3 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRT4 | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2
- PTF1A | c.659A>C p.Q220P | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- PTPRK | c.2359A>G p.M787V (on ENST00000368215 / NM_001291984.2; = p.M788V on NM_002844.4) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRN | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PXDNL | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFPL1 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 262/506 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RFX4 | c.2148G>A p.M716I (on ENST00000392842 / NM_213594.3; = p.M622I on NM_032491.6) | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); called by muse, mutect2
- RPA4 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RTN4R | c.93C>A p.C31* | Nonsense Mutation (SNP) | VAF 308/594 reads (52%) | called by muse, mutect2, varscan2
- RXFP2 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 98/431 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by mutect2, varscan2
- RYR2 | c.4325G>C p.W1442S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- SAMD9 | c.2998T>C p.Y1000H | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SCN1A | c.5463G>C p.Q1821H (on ENST00000303395 / NM_001202435.3; = p.Q1810H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SCN3A | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SELENOO | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 202/357 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SEMA6B | c.2182C>A p.H728N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2
- SH3GL1 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 157/585 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKIV2L | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC38A9 | c.1351A>T p.M451L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLFN14 | c.2315A>C p.E772A | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SMIM21 | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SPTA1 | c.6688G>T p.D2230Y | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAMBP | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYCE1 | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TAZ | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM144 | c.113T>G p.M38R | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TNIK | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 34/634 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2
- TRDN | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTN | c.13363T>C p.C4455R (on ENST00000591111; = p.C4409R on NM_003319.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.11621T>A p.I3874K (on ENST00000591111; = p.I3828K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- UHRF1 | c.473G>T p.R158M (on ENST00000612630 / NM_001290050.1; = p.R171M on NM_013282.4) | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- USP42 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 139/304 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- WDR90 | c.3211G>T p.A1071S | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WFIKKN2 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 109/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YTHDF3 | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZBTB38 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.3796A>G p.T1266A | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1322T>A p.M441K | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF319 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZNF44 | c.370G>C p.D124H (on ENST00000356109 / NM_001164276.2; = p.D76H on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF443 | c.1598A>G p.E533G | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ZNF804A | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACRBP | c.540A>G p.L180= | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- AIPL1 | c.423G>A p.Q141= | Silent (SNP) | VAF 237/439 reads (54%) | called by muse, mutect2, varscan2
- ANKRD33B | c.819C>T p.P273= | Silent (SNP) | VAF 138/1444 reads (10%) | catalogued as rs1285358717; called by muse, mutect2
- ASGR2 | c.834T>C p.C278= | Silent (SNP) | VAF 100/201 reads (50%) | called by muse, mutect2, varscan2
- ATPAF1 | c.192G>A p.G64= (on ENST00000574428; = p.G87= on NM_022745.4) | Silent (SNP) | VAF 63/223 reads (28%) | called by muse, mutect2, varscan2
- BEND2 | c.1320A>G p.V440= | Silent (SNP) | VAF 64/97 reads (66%) | catalogued as rs758848941; called by muse, mutect2, varscan2
- C1QL2 | c.111T>C p.T37= | Silent (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- CARD11 | c.1524G>A p.Q508= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV100829053, COSV100829130; called by muse, mutect2
- CDH26 | c.522G>A p.V174= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- CFAP65 | c.3492C>T p.P1164= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs568903495; called by muse, mutect2
- CLMP | c.132A>G p.K44= | Silent (SNP) | VAF 30/117 reads (26%) | called by muse, mutect2, varscan2
- CNNM2 | c.555G>A p.K185= | Silent (SNP) | VAF 187/682 reads (27%) | called by muse, mutect2, varscan2
- CNTFR | c.219G>A p.Q73= | Silent (SNP) | VAF 156/425 reads (37%) | called by muse, mutect2, varscan2
- COLEC12 | c.765G>A p.T255= | Silent (SNP) | VAF 82/257 reads (32%) | catalogued as rs746112930; called by muse, mutect2, varscan2
- COLGALT1 | c.1146C>T p.T382= | Silent (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- DNMT3L | c.39C>T p.P13= | Silent (SNP) | VAF 61/263 reads (23%) | called by muse, mutect2, varscan2
- DRC7 | c.963C>T p.D321= | Silent (SNP) | VAF 90/289 reads (31%) | catalogued as rs1388503282; called by muse, mutect2, varscan2
- DYNC1I1 | c.1263C>T p.D421= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as rs917675638; called by muse, mutect2, varscan2
- EFHC1 | c.768T>C p.Y256= | Silent (SNP) | VAF 123/401 reads (31%) | called by muse, mutect2, varscan2
- ERP44 | c.30C>T p.P10= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs769787882, COSV52434470; called by muse, mutect2, varscan2
- ETAA1 | c.84G>C p.S28= | Silent (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- FAAP24 | c.60G>T p.V20= | Silent (SNP) | VAF 52/217 reads (24%) | called by muse, mutect2, varscan2
- FRG1 | c.402A>T p.P134= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV57008177; called by muse, mutect2, varscan2
- G6PC | c.1038C>T p.A346= | Silent (SNP) | VAF 84/306 reads (27%) | catalogued as rs756155679; called by muse, mutect2, varscan2
- GATA4 | c.561G>T p.P187= | Silent (SNP) | VAF 368/628 reads (59%) | called by muse, mutect2, varscan2
- GPR161 | c.780C>T p.V260= | Silent (SNP) | VAF 87/347 reads (25%) | catalogued as COSV54788421, COSV99607336; called by muse, mutect2, varscan2
- GUCY1A2 | c.1023G>A p.Q341= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs1409020605; called by muse, mutect2, varscan2
- GYG2 | c.729C>T p.V243= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs759268550; called by muse, mutect2
- HMCN1 | c.3408G>A p.K1136= | Silent (SNP) | VAF 14/451 reads (3%) | called by muse, mutect2
- IGKV6D-21 | c.129G>T p.R43= | Silent (SNP) | VAF 53/319 reads (17%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.297G>T p.A99= | Silent (SNP) | VAF 62/297 reads (21%) | called by muse, mutect2, varscan2
- ILDR2 | c.936G>T p.L312= | Silent (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- KLHL26 | c.687G>C p.A229= | Silent (SNP) | VAF 158/593 reads (27%) | catalogued as rs150852328; called by muse, mutect2, varscan2
- KRT84 | c.1509C>G p.A503= | Silent (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- LACRT | c.42G>T p.G14= | Silent (SNP) | VAF 47/226 reads (21%) | called by muse, mutect2, varscan2
- LCT | c.3441G>T p.L1147= | Silent (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3036G>C p.V1012= | Silent (SNP) | VAF 66/263 reads (25%) | called by muse, mutect2, varscan2
- MCAM | c.780A>G p.G260= | Silent (SNP) | VAF 75/344 reads (22%) | catalogued as rs776109784; called by muse, mutect2, varscan2
- MUC16 | c.34383C>A p.T11461= | Silent (SNP) | VAF 48/162 reads (30%) | called by muse, mutect2, varscan2
- MYH4 | c.5685C>G p.V1895= | Silent (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- NOL4L | c.504G>C p.P168= | Silent (SNP) | VAF 93/218 reads (43%) | catalogued as rs540662301; called by muse, mutect2, varscan2
- NPAP1 | c.748C>A p.R250= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as rs200510789, COSV100274923, COSV61511489; called by muse, mutect2, varscan2
- NR6A1 | c.1395C>G p.L465= (on ENST00000487099 / NM_033334.4; = p.L460= on NM_001489.5) | Silent (SNP) | VAF 53/158 reads (34%) | called by muse, mutect2, varscan2
- NRAP | c.1437T>C p.Y479= (on ENST00000359988 / NM_001322945.2; = p.Y444= on NM_006175.4) | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs541519788; called by muse, mutect2, varscan2
- NSD2 | c.2154C>T p.F718= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs769815661; called by muse, mutect2, varscan2
- OR1S1 | c.444C>A p.L148= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as COSV58708424; called by muse, mutect2, varscan2
- OR2M4 | c.90G>T p.L30= | Silent (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- OR2T6 | c.309C>T p.L103= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- OR4A15 | c.561C>T p.C187= | Silent (SNP) | VAF 45/178 reads (25%) | catalogued as rs142374591; called by muse, mutect2, varscan2
- OR4X1 | c.228C>T p.A76= | Silent (SNP) | VAF 115/487 reads (24%) | catalogued as COSV99082046; called by muse, mutect2, varscan2
- OR51S1 | c.510G>T p.L170= | Silent (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- PAPSS2 | c.963T>A p.G321= | Silent (SNP) | VAF 141/663 reads (21%) | called by muse, mutect2, varscan2
- PARD6A | c.393G>A p.L131= | Silent (SNP) | VAF 73/181 reads (40%) | called by muse, mutect2, varscan2
- PCDH12 | c.2052C>T p.P684= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as rs553472671; called by muse, mutect2, varscan2
- PCNX1 | c.2655G>A p.E885= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs746276695; called by muse, mutect2, varscan2
- PDE4D | c.1291C>A p.R431= (on ENST00000340635 / NM_001104631.2; = p.R295= on NM_006203.4) | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV57715208; called by muse, mutect2
- PHF8 | c.2853G>C p.L951= (on ENST00000357988 / NM_001184896.1; = p.L915= on NM_015107.3) | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- PPP1R3A | c.1860A>G p.S620= | Silent (SNP) | VAF 71/281 reads (25%) | called by muse, mutect2, varscan2
- PRR36 | c.603G>T p.P201= | Silent (SNP) | VAF 47/173 reads (27%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.237C>T p.S79= | Silent (SNP) | VAF 64/319 reads (20%) | called by muse, mutect2, varscan2
- PTPRN | c.438C>A p.P146= | Silent (SNP) | VAF 58/306 reads (19%) | called by mutect2, varscan2
- RAC1 | c.153G>A p.V51= | Silent (SNP) | VAF 80/245 reads (33%) | called by muse, mutect2, varscan2
- RNF213 | c.13278T>C p.S4426= | Silent (SNP) | VAF 64/277 reads (23%) | called by muse, mutect2, varscan2
- ROBO3 | c.1779C>G p.A593= | Silent (SNP) | VAF 38/173 reads (22%) | called by muse, mutect2, varscan2
- RP1 | c.1126C>A p.R376= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as COSV55110199; called by muse, mutect2, varscan2
- RYR1 | c.5778G>C p.L1926= | Silent (SNP) | VAF 87/289 reads (30%) | catalogued as rs754492782; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN4A | c.1506T>C p.H502= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- SLC6A16 | c.1314A>G p.P438= | Silent (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1965G>C p.V655= | Silent (SNP) | VAF 191/380 reads (50%) | called by muse, mutect2, varscan2
- SNX29 | c.1884C>T p.I628= | Silent (SNP) | VAF 105/309 reads (34%) | catalogued as rs376970358; called by muse, mutect2, varscan2
- TAS1R1 | c.2523C>A p.T841= | Silent (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- THSD7A | c.1002G>T p.T334= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV70274703; called by muse, mutect2, varscan2
- TNXB | c.6306C>T p.P2102= (on ENST00000647633; = p.P1855= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- TPCN2 | c.2148C>T p.A716= | Silent (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- TRPC5 | c.288G>T p.V96= | Silent (SNP) | VAF 64/128 reads (50%) | called by muse, mutect2, varscan2
- TTLL1 | c.382C>A p.R128= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.89130G>C p.S29710= (on ENST00000591111; = p.S22286= on NM_003319.4) | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as COSV60386956; called by muse, mutect2, varscan2
- TYSND1 | c.1560G>T p.T520= | Silent (SNP) | VAF 50/205 reads (24%) | called by muse, mutect2, varscan2
- UNC79 | c.37C>A p.R13= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- USP17L18 | c.1167G>A p.R389= | Silent (SNP) | VAF 28/1455 reads (2%) | called by muse, mutect2
- VAMP3 | c.204G>A p.K68= | Silent (SNP) | VAF 45/172 reads (26%) | called by muse, mutect2, varscan2
- ZC3H7A | c.2229G>T p.R743= | Silent (SNP) | VAF 53/231 reads (23%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5695C>A p.R1899= | Silent (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- ZNF644 | c.354A>G p.G118= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- ZNF704 | c.429C>A p.S143= | Silent (SNP) | VAF 102/621 reads (16%) | called by muse, mutect2, varscan2
- A4GALT | c.*8G>T | 3'UTR (SNP) | VAF 67/378 reads (18%) | catalogued as COSV99966655; called by muse, mutect2, varscan2
- AC009093.9 | n.183G>A | RNA (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- AC073621.1 | n.366A>G | RNA (SNP) | VAF 149/370 reads (40%) | called by muse, mutect2, varscan2
- AC106038.2 | chr8:90703396 G>A | 3'Flank (SNP) | VAF 17/114 reads (15%) | catalogued as rs1456543307, COSV101581319; called by muse, mutect2, varscan2
- AL353753.1 | n.492G>T | RNA (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.1015-20dup | Intron (INS) | VAF 46/211 reads (22%) | called by mutect2, pindel, varscan2
- ATP8A2P3 | n.472C>T | RNA (SNP) | VAF 18/78 reads (23%) | catalogued as rs1314763518; called by muse, mutect2
- C4orf3 | chr4:119300653 C>G | 5'Flank (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2, varscan2
- CCNC | c.798-605C>G | Intron (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- CLOCK | c.-15A>T | 5'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- COL3A1 | c.*20C>T | 3'UTR (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2
- COL4A3 | c.2746+31G>A | Intron (SNP) | VAF 17/246 reads (7%) | catalogued as rs1486668562; called by muse, mutect2
- COL9A3 | c.1549-20A>G | Intron (SNP) | VAF 76/339 reads (22%) | called by muse, mutect2
- DENND10P1 | n.1079C>A | RNA (SNP) | VAF 103/222 reads (46%) | called by muse, mutect2, varscan2
- DENND10P1 | n.1080C>T | RNA (SNP) | VAF 101/216 reads (47%) | called by muse, mutect2, varscan2
- DNAH5 | c.2259+26C>A | Intron (SNP) | VAF 21/256 reads (8%) | catalogued as rs749131212; called by muse, mutect2
- ERCC4 | c.389-9C>T | Intron (SNP) | VAF 54/240 reads (23%) | called by muse, mutect2, varscan2
- FAM81A | c.-45G>C | 5'UTR (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643978 C>T | 5'Flank (SNP) | VAF 58/365 reads (16%) | catalogued as rs1281124936; called by mutect2, varscan2
- KIR3DX1 | n.927del | RNA (DEL) | VAF 38/161 reads (24%) | catalogued as COSV55600194; called by mutect2, pindel, varscan2
- KIRREL1 | c.*1851G>T | 3'UTR (SNP) | VAF 58/251 reads (23%) | called by muse, mutect2, varscan2
- KLF6 | c.*2277A>G | 3'UTR (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- LINC01387 | n.381G>A | RNA (SNP) | VAF 106/274 reads (39%) | called by muse, mutect2, varscan2
- MAN2B2 | c.-8C>A | 5'UTR (SNP) | VAF 97/380 reads (26%) | catalogued as COSV99577212; called by muse, mutect2, varscan2
- MFSD1 | chr3:158802014 G>A | 5'Flank (SNP) | VAF 57/154 reads (37%) | catalogued as rs1055773380; called by muse, mutect2, varscan2
- MYPN | c.*941G>C | 3'UTR (SNP) | VAF 56/219 reads (26%) | called by muse, mutect2, varscan2
- NR4A1 | c.160+3635del | Intron (DEL) | VAF 33/149 reads (22%) | called by pindel, varscan2*
- OFCC1 | n.568C>G | RNA (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- OR4F13P | n.866T>A | RNA (SNP) | VAF 59/230 reads (26%) | called by muse, mutect2, varscan2
- PKM | c.566-47C>T | Intron (SNP) | VAF 55/202 reads (27%) | catalogued as rs774529400; called by muse, mutect2, varscan2
- PPY2P | n.462A>C | RNA (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- SLC13A5 | c.369-309G>A | Intron (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- SLC25A25 | c.262-9060G>A | Intron (SNP) | VAF 52/151 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25087856 G>A | 3'Flank (SNP) | VAF 61/222 reads (27%) | called by muse, mutect2, varscan2
- SNRPN | c.-336G>T | 5'UTR (SNP) | VAF 117/419 reads (28%) | called by muse, mutect2, varscan2
- STRA6 | c.431-15T>C | Intron (SNP) | VAF 94/367 reads (26%) | called by muse, mutect2, varscan2
- TMEM40 | c.-37C>G | 5'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- TRIML1 | c.736-26C>A | Intron (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10360+2355A>T | Intron (SNP) | VAF 34/153 reads (22%) | called by muse, mutect2, varscan2
- UBBP4 | n.895C>A | RNA (SNP) | VAF 128/518 reads (25%) | called by muse, mutect2, varscan2
- WDFY4 | c.1878+28G>C | Intron (SNP) | VAF 71/283 reads (25%) | called by muse, mutect2, varscan2
- ZNF875 | c.-84A>G | 5'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
